Somatic mutation profile of tumor specimen MMRF_2125_1_BM_CD138pos (aliquot MMRF_2125_1_BM_CD138pos_T1_KHS5U_L08668) from MMRF case MMRF_2125, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.6 years (19,958 days).
Specimen MMRF_2125_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3eb73ee-cbaa-4b3c-a76f-370e0cc63be7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2125_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2125_1_PB_CD3pos_C3_KHS5U_L08667; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38f1bf3d-0772-4037-b98a-2e3309582eb8

The open-access MAF lists 42 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 14, Missense Mutation 12, Intron 5, 5'UTR 3, Silent 2, RNA 2, Splice Region 1, 5'Flank 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNRIP1 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99721101; called by muse, mutect2, varscan2
- IGKV5-2 | c.218C>G p.T73S | Missense Mutation (SNP) | VAF 28/28 reads (100%) | SIFT tolerated (0.77); PolyPhen benign (0.2); catalogued as rs774400959; called by mutect2, varscan2
- MAGEB18 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs185512032, COSV57463787; called by muse, mutect2, varscan2
- MYH2 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs578188627, COSV55443758; ClinVar: uncertain significance; called by muse, mutect2
- NBEAL1 | c.2366T>C p.I789T | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.32); PolyPhen benign (0.212); catalogued as rs1303469029; called by muse, mutect2, varscan2
- NUCB1 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs886157097, COSV54387757; called by muse, mutect2, varscan2
- WDR55 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.743); catalogued as rs367668945; called by muse, mutect2, varscan2
- YLPM1 | c.6135G>A p.W2045* | Nonsense Mutation (SNP) | VAF 76/160 reads (48%) | catalogued as COSV99459297; called by muse, mutect2, varscan2
- DIP2C | c.3625G>A p.E1209K | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- EGFR | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 18/241 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); called by muse, mutect2
- FAT4 | c.2409T>G p.F803L | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.981); called by muse, mutect2
- FCF1 | c.61_71+5delinsATGCT p.X21_splice | Splice Site (DEL) | VAF 50/144 reads (35%) | called by pindel, varscan2*
- MLLT10 | c.1053C>T p.G351= | Splice Region (SNP) | VAF 9/15 reads (60%) | called by mutect2, varscan2
- NRK | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 27/27 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STXBP4 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGLV3-1 | c.333C>T p.S111= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as rs151220536; called by muse, varscan2
- TEKT2 | c.924C>T p.L308= | Silent (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- AC093791.1 | n.428G>A | RNA (SNP) | VAF 9/28 reads (32%) | catalogued as rs1004923771; called by muse, mutect2, varscan2
- ANKRD10 | c.691+138G>C | Intron (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- AOC4P | n.1319G>A | RNA (SNP) | VAF 17/37 reads (46%) | catalogued as rs1294350781; called by muse, mutect2, varscan2
- BARD1 | c.-94C>T | 5'UTR (SNP) | VAF 19/58 reads (33%) | catalogued as rs956478066; called by muse, mutect2, varscan2
- BCL7A | chr12:122021208 G>A | 5'Flank (SNP) | VAF 37/83 reads (45%) | catalogued as rs554259957; called by muse, mutect2, varscan2
- BLOC1S4 | c.*195dup | 3'UTR (INS) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- BMP3 | c.*113G>A | 3'UTR (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- CHRM3 | c.*2116del | 3'UTR (DEL) | VAF 14/160 reads (9%) | called by mutect2, pindel
- CNTN5 | c.-32C>A | 5'UTR (SNP) | VAF 21/278 reads (8%) | called by muse, mutect2
- CSTF2T | c.*1270C>G | 3'UTR (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- DIS3 | c.*1598C>T | 3'UTR (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- EPHA7 | c.*3072T>G | 3'UTR (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- HMGA2 | c.282+2611A>T | Intron (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- JCAD | c.*1181A>G | 3'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- KCNE1B | c.*1407C>T | 3'UTR (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2
- PCSK6 | c.2699+231A>T | Intron (SNP) | VAF 11/75 reads (15%) | catalogued as rs1567136638; called by muse, mutect2, varscan2
- PTGS2 | c.*1459del | 3'UTR (DEL) | VAF 10/30 reads (33%) | catalogued as rs887190876; called by mutect2, varscan2
- RAD52 | c.*1147G>A | 3'UTR (SNP) | VAF 5/12 reads (42%) | catalogued as rs1290461060; called by muse, mutect2, varscan2
- SENP1 | c.221-297G>C | Intron (SNP) | VAF 29/66 reads (44%) | catalogued as rs755474635; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.*2330A>C | 3'UTR (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- STYK1 | c.*160G>A | 3'UTR (SNP) | VAF 4/30 reads (13%) | catalogued as rs962349465; called by muse, mutect2
- TBX18 | c.*2043T>A | 3'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- TNRC6A | c.5303-11del | Intron (DEL) | VAF 3/34 reads (9%) | called by pindel, varscan2
- TUBB2B | c.*294C>A | 3'UTR (SNP) | VAF 25/55 reads (45%) | called by muse, varscan2
- UHRF2 | c.-45G>C | 5'UTR (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
